Gene-level copy-number profile of tumor specimen MP2PRT-PAVGZX-TMP1-A from MP2PRT case MP2PRT-PAVGZX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (426 days).
Specimen MP2PRT-PAVGZX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 991489c8-08c7-4499-a733-a137254e13fa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVGZX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/d506d215-75ea-4f9b-bb82-00d5feee347f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 96; copy number 2: 58,242; copy number 3: 34.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,947,301–88,979,081, 3 genes (within-gene range 0–1): IGKV1-5, IGKV1-6, IGKV3-7.
- chr2:89,009,982–89,010,515, 1 gene (within-gene range 0–1): IGKV1-9.
- chr2:89,027,171–89,245,596, 19 genes (within-gene range 0–1): IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
